Somatic mutation profile of tumor specimen 0DKDEF from CCDI case PBBXZS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 16.3 years (5,951 days).
Specimen 0DKDEF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 153b36bd-adc7-4c7a-b91e-bc4567d0a77a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKDBY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4819b042-e426-42bc-a38d-84b143bc0472

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAM | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 104/1095 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.435); catalogued as rs755676603, COSV68026464; called by muse, mutect2
- LSAMP | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 102/582 reads (18%) | catalogued as COSV100372919; called by muse, mutect2, varscan2
- MYT1 | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 261/1149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767677746, COSV60512565; called by muse, mutect2, varscan2
- ADGRV1 | c.15808G>A p.E5270K | Missense Mutation (SNP) | VAF 128/1571 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.115); called by muse, mutect2
- GEMIN5 | c.1018T>G p.L340V | Missense Mutation (SNP) | VAF 116/1142 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- MPHOSPH8 | c.369+1G>T p.X123_splice | Splice Site (SNP) | VAF 448/796 reads (56%) | called by mutect2, varscan2
- MRPL53 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 109/1088 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2
- RGPD4 | c.4834C>T p.Q1612* | Nonsense Mutation (SNP) | VAF 88/254 reads (35%) | called by muse, mutect2, varscan2
- SAC3D1 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 191/471 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- SPATA5L1 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 140/445 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- TSPAN8 | c.141del p.D47Efs*2 | Frame Shift Del (DEL) | VAF 87/833 reads (10%) | called by mutect2, pindel, varscan2
- TTN | c.47459C>G p.P15820R (on ENST00000591111; = p.P8396R on NM_003319.4) | Missense Mutation (SNP) | VAF 420/984 reads (43%) | PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FSTL5 | c.510C>T p.G170= | Silent (SNP) | VAF 105/674 reads (16%) | catalogued as rs764235242, COSV60213328, COSV60214416; called by muse, mutect2, varscan2
- NAV3 | c.7095C>T p.C2365= (on ENST00000397909 / NM_001024383.2; = p.C2343= on NM_014903.6) | Silent (SNP) | VAF 164/1121 reads (15%) | catalogued as rs763140795, COSV57085656; called by muse, mutect2, varscan2
- PTPRO | c.2883G>A p.L961= (on ENST00000281171 / NM_030667.3; = p.L933= on NM_002848.4) | Silent (SNP) | VAF 159/1361 reads (12%) | catalogued as rs200417811; called by muse, mutect2, varscan2
- RGL3 | c.2020C>T p.L674= | Silent (SNP) | VAF 650/741 reads (88%) | catalogued as COSV100992889; called by muse, mutect2, varscan2
- RNASEH2A | c.*10C>G | 3'UTR (SNP) | VAF 1311/1619 reads (81%) | called by muse, mutect2, varscan2
- THRA | c.1110+73G>A | Intron (SNP) | VAF 157/1527 reads (10%) | catalogued as rs772978092, COSV52842723; called by muse, mutect2, varscan2
